Somatic mutation profile of tumor specimen TARGET-30-PARMPP-01A (aliquot TARGET-30-PARMPP-01A-01D) from TARGET case TARGET-30-PARMPP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.8 years (1,370 days).
Specimen TARGET-30-PARMPP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 545eb2f6-d581-4cf3-ae11-0aab12ef06bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARMPP-10A (Blood Derived Normal), aliquot TARGET-30-PARMPP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be769eb6-3089-4211-91a6-ed24b435d546

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1670C>A p.T557K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as COSV58644241; called by muse, mutect2, varscan2
- ADGRE1 | c.327A>T p.L109F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV51676551; called by muse, varscan2
- ADGRF5 | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV51935042; called by muse, mutect2, varscan2
- ASB4 | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs748097345, COSV57945775; called by muse, mutect2, varscan2
- BPIFA1 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV62824637; called by muse, mutect2, varscan2
- CDH9 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.768); catalogued as COSV50298808; called by muse, mutect2, varscan2
- DHX8 | c.3388C>G p.Q1130E | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV52253917; called by muse, mutect2, varscan2
- DOCK8 | c.2142G>T p.W714C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66620703; called by muse, mutect2, varscan2
- DSG3 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57126939; called by muse, mutect2, varscan2
- FSHB | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV54222177; called by muse, mutect2, varscan2
- GOLIM4 | c.1292A>T p.Q431L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58330099; called by muse, mutect2, varscan2
- IGBP1 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60556532; called by muse, mutect2, varscan2
- KIAA1109 | c.5143G>T p.V1715L | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52676857; called by muse, mutect2, varscan2
- LARS1 | c.2992-1G>A p.X998_splice (on ENST00000394434 / NM_020117.11; = p.X971_splice on NM_016460.3) | Splice Site (SNP) | VAF 23/44 reads (52%) | catalogued as COSV50978508; called by muse, mutect2, varscan2
- LRFN4 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1290542436, COSV100540904, COSV58921847; called by muse, mutect2, varscan2
- LRP10 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62078408; called by muse, mutect2, varscan2
- MYO1F | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs201138222, COSV57796026; called by muse, mutect2, varscan2
- NIBAN2 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); catalogued as COSV64823649, COSV64824539; called by muse, mutect2, varscan2
- OR51A2 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66748478, COSV66748533; called by muse, mutect2, varscan2
- PRRC2B | c.4279G>A p.V1427M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs201739719; called by muse, mutect2
- RECQL5 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100511756; called by muse, mutect2
- RIPOR1 | c.3067G>A p.A1023T (on ENST00000379312 / NM_001193522.2; = p.A1019T on NM_024519.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV50227681; called by muse, mutect2, varscan2
- SUCLA2 | c.1177G>A p.A393T (on ENST00000643023; = p.A372T on NM_003850.3) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV66222357; called by muse, mutect2
- TAOK1 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.983); catalogued as rs1398510704, COSV55592866; called by muse, mutect2, varscan2
- UGT2B10 | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55321100, COSV55321680; called by muse, mutect2, varscan2
- CBX2 | c.967A>T p.N323Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- COL18A1 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GALNT5 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF2C | c.606_608del p.K202del | In Frame Del (DEL) | VAF 11/35 reads (31%) | called by pindel, varscan2
- CBX2 | c.966G>A p.G322= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs782787780; called by muse, mutect2
- FRY | c.8898G>A p.V2966= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV66511274; called by muse, mutect2, varscan2
- GALNT5 | c.609C>A p.P203= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV52036238; called by muse, mutect2, varscan2
- KIAA1549 | c.4806C>T p.R1602= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54316682; called by muse, mutect2, varscan2
- PCDHA6 | c.1449C>T p.D483= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as rs1554132062, COSV100971799, COSV65344704, COSV65346009; called by muse, mutect2, varscan2
- PPFIA1 | c.1290G>T p.L430= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1209686598, COSV54135989; called by muse, mutect2, varscan2
- CSTA | c.*1C>A | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
